Surgical pathology report (de-identified scan), TCGA case TCGA-G7-A8LD, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Roswell Park, specimen TCGA-G7-A8LD-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3
Carcinoma, papillary renal cell
8260/3
Site @ Kidney NOS C64.9
JW 11/24/13

SPECIMENS:

- A. LEFT KIDNEY
- B. LEFT PERIAORTIC LYMPH NODES

SPECIMEN(S):

- A. LEFT KIDNEY
- B. LEFT PERIAORTIC LYMPH NODES

DIAGNOSIS:

- A. KIDNEY, LEFT, NEPHRECTOMY:
- PAPILLARY RENAL CELL CARCINOMA (7.5 X 6.3 X 6.1 CM.), TYPE II, FUHRMAN NUCLEAR GRADE 3
- TUMOR EXTENDS INTO PERINEPHRIC AND RENAL SINUS ADIPOSE TISSUE
- LYMPHOVASCULAR INVASION IDENTIFIED
- SURGICAL MARGINS NEGATIVE FOR CARCINOMA
- SEE SYNOPTIC REPORT
- B. LYMPH NODE, PERIAORTIC, LEFT, EXCISION:
- NINE OUT OF ELEVEN LYMPH NODES POSITIVE FOR METASTATIC CARCINOMA (9/11)

SYNOPTIC REPORT - KIDNEY (PARTIAL OR RADICAL)

Specimens Involved

Specimens: A: LEFT KIDNEY

B: LEFT PERIAORTIC LYMPH NODES

Specimen Type: Radical nephrectomy

With adrenal gland

Laterality: Left

Tumor Site: Lower pole

Focality: Unifocal

Tumor Size (largest tumor if multiple): Greatest dimension: 7.5cm

Additional dimensions: 6.3cm x 6.1cm

Macroscopic Extent of Tumor: Tumor extension into perinephric tissues

WHO CLASSIFICATION

Papillary renal cell carcinoma 8260/3

Histologic Grade (Fuhrman Nuclear Grade):

G3: Nuclei very irregular, approximately 20 u; nucleoli large and prominent

Invasion of Vascular/Lymphatic: Present

Perinephric Tissue Invasion: Present

Margins: Margins uninvolved by invasive carcinoma

Adrenal Gland: Uninvolved by tumor

Regional Lymph Nodes: Positive 9 / 11

Additional Findings: None identified

Pathological Staging (pTNM): pT 3a N 1 M X

Pathological staging is based on the AJCC Cancer Staging Manual, 7th Edition

GROSS DESCRIPTION:

A. LEFT KIDNEY

Received fresh labeled with the patient's identification and "left kidney" is a 1036 g kidney with attached perinephric fat, 24 x 9 x 8.3 cm. The adrenal gland is golden-orange and measures 1.4 x 0.5 x 0.4 cm. The ureter is 9.5 x 0.3 cm; it is probe patent and contains a green Teflon catheter. The specimen is inked black; it is bisected. The kidney is 19 x 7.8 x 5.5 cm. The renal pelvis is dilated and protruding from the calyx into the pelvis is a friable brown-tan hemorrhagic mass. The lower pole contains a friable, papillary, hemorrhagic golden tan necrotic mass, 7.5 x 6.3 x 6.1 cm. The mass grossly extends into the renal pelvis and pushes on the capsule. The renal fat surrounding the mass is edematous. The soft tissue surrounding the dilated renal pelvis has a white-yellow discoloration. The remainder of the parenchyma is unremarkable. Photograph is taken and tissue is procured; representatively submitted:

[page 2 of 2]
A1: shave of ureter margin
A2: shave of vasculature margins
A3: adrenal gland
A4-A6: mass and relationship to renal sinus and pelvis
A7: hemorrhagic and necrotic a portion of the mass
A8-A10: mass in relationship to capsule and perinephric fat
A11-A12: mass and edematous fat
A13: area of discoloration surrounding renal pelvis
A14: normal appearing parenchyma

B. LEFT PERIAORTIC LYMPH NODES

Received without fixative in a container labeled with the patient's identification and designated "periaortic lymph nodes" are multiple fragments of fibroadipose tissue measuring 8.5 x 7.9 x 1.8 cm in aggregate. Sectioning shows multiple possible lymph nodes ranging from 0.9 x 0.5 x 0.4 up to 3.2 x 1.2 x 1.2 cm. Cassettes are submitted as follows:

B1: 3 possible lymph nodes
B2: 2 possible lymph nodes
B3: One lymph node
B4-B5: One lymph node
B6: Representative sections, one lymph node
B7: Representative sections, one lymph node
B8: Representative sections one lymph node
B9-B10: One lymph node

CLINICAL HISTORY:

None Given

PRE-OPERATIVE DIAGNOSIS:

Left kidney mass

Gross Dictation:., Pathologist,
Microscopic/Diagnostic Dictation:..
Final Review: Pathologist,
Final Review:., Pathologist,
Final Review: Pathologist,
Final:., Pathologist,

Dual/Synchronous Markedly Noted		/

Source: NCI Genomic Data Commons file 84c73ac2-7e69-4397-bdc3-7e0d2edba5a7 (TCGA-G7-A8LD.7A18CAC6-457B-4CB1-9998-14772FF66370.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).